Somatic mutation profile of tumor specimen TCGA-V1-A9Z7-01A (aliquot TCGA-V1-A9Z7-01A-11D-A41K-08) from TCGA case TCGA-V1-A9Z7, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A9Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82baa069-2afd-4089-b8e5-9e2714dc3538.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A9Z7-10A (Blood Derived Normal), aliquot TCGA-V1-A9Z7-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e95b2c9e-9dfb-4b84-a148-b74657eac3af

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 19, Silent 7, Splice Site 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUL3 | c.896T>G p.M299R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV52362904; called by muse, mutect2, varscan2
- FARS2 | c.431A>G p.Y144C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397514610, CM123187, COSV99212976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.11015dup p.S3673Qfs*4 | Frame Shift Ins (INS) | VAF 16/177 reads (9%) | catalogued as rs760635510; called by mutect2, pindel
- AGO4 | c.2175+1G>A p.X725_splice | Splice Site (SNP) | VAF 12/70 reads (17%) | catalogued as COSV100942909; called by muse, varscan2
- AK8 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.131); catalogued as rs547319863, COSV100049926; called by muse, mutect2, varscan2
- ANK1 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 29/962 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV55880939; called by muse, mutect2
- ANKZF1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs762023095, COSV55476183, COSV55476909; called by muse, mutect2, varscan2
- CCR5 | c.851C>G p.T284S | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV99433335; called by muse, mutect2
- DEFB129 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV99857416; called by muse, mutect2, varscan2
- DPM1 | c.513A>T p.L171F | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as COSV100857714; called by muse, mutect2, varscan2
- ERBB4 | c.2683A>G p.R895G | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); catalogued as COSV100725142; called by muse, varscan2
- FH | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100845014; called by muse, mutect2
- FRK | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV101606644; called by muse, mutect2, varscan2
- LCT | c.2866T>G p.Y956D | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99929267; called by muse, mutect2, varscan2
- LPP | c.410A>G p.Y137C | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756147443, COSV100446809; called by muse, mutect2, varscan2
- MSANTD4 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1302847787, COSV100108545; called by muse, mutect2, varscan2
- NPAS4 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs765475757, COSV100214969; called by muse, mutect2, varscan2
- PRSS8 | c.601T>A p.C201S | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99571386; called by muse, mutect2, varscan2
- TUBG2 | c.1046T>G p.I349S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99257503; called by muse, mutect2, varscan2
- WDR93 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs376704792, COSV99175872; called by muse, mutect2
- ZNF91 | c.1441A>G p.K481E | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV100322583; called by muse, mutect2, varscan2
- IREB2 | c.2415del p.F805Lfs*21 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, pindel, varscan2
- TP53 | c.773_782+1del p.X258_splice | Splice Site (DEL) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- COL27A1 | c.1785G>A p.A595= | Silent (SNP) | VAF 26/83 reads (31%) | catalogued as rs781558892, COSV61931796; called by muse, mutect2, varscan2
- DPP9 | c.1296A>G p.Q432= (on ENST00000598800; = p.Q461= on NM_139159.5) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs549939671, COSV99506020; called by muse, mutect2, varscan2
- FUT7 | c.633C>T p.C211= | Silent (SNP) | VAF 18/194 reads (9%) | catalogued as rs751230175, COSV99687493; called by muse, mutect2
- MRPS18B | c.687C>T p.G229= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as COSV52541122; called by muse, mutect2, varscan2
- NOTCH3 | c.5466C>T p.S1822= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs148053028, COSV99656856; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR6S1 | c.147G>C p.G49= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV100289350, COSV57839402; called by muse, mutect2, varscan2
- PRDM2 | c.4239G>C p.S1413= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as COSV52447581, COSV52451931; called by muse, mutect2, varscan2
